Somatic mutation profile of tumor specimen 0DDEQG from CCDI case PBBNFX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DDEQG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1046563-6547-4cd2-83f1-54233317a347.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDERH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6240861-f122-46ca-95ab-121db7f7d369

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 4 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Intron 8, Silent 4, 3'UTR 2, Splice Region 1, 5'UTR 1, Nonsense Mutation 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 99/327 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 26/285 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ANK1 | c.4154G>C p.R1385P | Missense Mutation (SNP) | VAF 23/654 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV55899098; called by muse, mutect2
- CEP170 | c.800C>G p.T267R | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100317099; called by muse, mutect2
- CSMD3 | c.7987C>G p.R2663G (on ENST00000297405 / NM_001363185.1; = p.R2559G on NM_052900.3) | Missense Mutation (SNP) | VAF 46/858 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV52100177, COSV52156018; called by muse, mutect2
- DAGLB | c.301C>G p.R101G | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99765597; called by muse, mutect2, varscan2
- FLG | c.9152G>A p.R3051Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs766570371; called by mutect2, varscan2
- IPO8 | c.2336G>C p.R779P | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56242352; called by muse, mutect2
- TENM3 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.209); catalogued as rs751685257; called by muse, mutect2
- ZNF213 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV67727881; called by muse, mutect2, varscan2
- AC010255.2 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 88/303 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ANKRD45 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.057); called by muse, mutect2
- ATR | c.5562G>T p.L1854F | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 18/156 reads (12%) | called by muse, varscan2
- CECR2 | c.2719G>A p.A907T (on ENST00000342247 / NM_001290047.2; = p.A724T on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CFLAR | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 45/449 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DSG4 | c.917A>C p.Q306P | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- KIAA1328 | c.678A>T p.R226S | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.306); called by muse, mutect2
- KIAA1671 | c.4256G>C p.R1419P | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF25 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB5 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2
- PABPC1L | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2
- RFX7 | c.820C>T p.Q274* (on ENST00000559447 / NM_001368074.1; = p.Q371* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/147 reads (11%) | called by muse, varscan2
- RP1 | c.1793A>T p.Y598F | Missense Mutation (SNP) | VAF 44/801 reads (5%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.454); called by muse, mutect2
- STXBP2 | c.1455_1480del p.X485_splice | Splice Site (DEL) | VAF 30/154 reads (19%) | called by mutect2, varscan2
- TCP11L1 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 21/384 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- UTP14C | c.1583G>T p.R528I | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2
- WDR11 | c.2302G>C p.A768P | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2
- ZNF658 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 56/280 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.235); called by muse, varscan2
- FRY | c.6294C>A p.S2098= | Silent (SNP) | VAF 18/337 reads (5%) | catalogued as COSV100969767; called by muse, mutect2
- KRTAP25-1 | c.136T>C p.L46= | Silent (SNP) | VAF 32/544 reads (6%) | catalogued as rs1287242467; called by muse, mutect2
- RBMX | c.960T>C p.Y320= | Silent (SNP) | VAF 77/336 reads (23%) | called by muse, mutect2, varscan2
- THSD7B | c.717T>C p.Y239= | Silent (SNP) | VAF 36/400 reads (9%) | called by muse, mutect2
- ATG16L2 | c.888-65C>A | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- BTG1 | c.-277C>G | 5'UTR (SNP) | VAF 101/522 reads (19%) | catalogued as rs976718738; called by muse, mutect2, varscan2
- COG7 | c.*86G>T | 3'UTR (SNP) | VAF 12/122 reads (10%) | called by muse, varscan2
- GFOD1 | c.253+16109C>G | Intron (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- IGFN1 | c.1241+1603C>G | Intron (SNP) | VAF 40/120 reads (33%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- MED10 | c.206+93T>A | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- NIT1 | c.3-16A>G | Intron (SNP) | VAF 14/161 reads (9%) | called by muse, mutect2
- NR4A3 | c.*72G>C | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, varscan2
- PGA3 | c.56+44C>G | Intron (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- SLC5A10 | c.1241+2108del | Intron (DEL) | VAF 57/177 reads (32%) | called by mutect2, varscan2
- UQCC1 | chr20:35412016 C>G | 5'Flank (SNP) | VAF 64/223 reads (29%) | called by muse, mutect2, varscan2
